Somatic mutation profile of tumor specimen TCGA-VQ-A8PJ-01A (aliquot TCGA-VQ-A8PJ-01A-11D-A410-08) from TCGA case TCGA-VQ-A8PJ, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IV; Tumor grade: GX; Age at diagnosis: 53.1 years (19,390 days).
Specimen TCGA-VQ-A8PJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7f1d149-0a10-4280-8ee8-b2233bd6754f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A8PJ-10A (Blood Derived Normal), aliquot TCGA-VQ-A8PJ-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9232b635-d8a1-4044-a285-eca72bda4356

The open-access MAF lists 172 somatic variants for this specimen: 127 protein-altering or splice-affecting, 39 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 115, Silent 39, Nonsense Mutation 5, 5'Flank 2, Nonstop Mutation 2, RNA 2, Intron 1, In Frame Del 1, Translation Start Site 1, Frame Shift Ins 1, In Frame Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCG2 | c.817G>T p.A273S | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV99420219; called by muse, mutect2, varscan2
- AC004922.1 | c.1180C>T p.P394S | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.325); catalogued as COSV99403113; called by muse, mutect2, varscan2
- ADCY6 | c.1492G>T p.D498Y | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100326931, COSV57169147; called by muse, mutect2, varscan2
- AL662899.2 | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as COSV101021782; called by muse, mutect2, varscan2
- AMOTL2 | c.2092C>T p.R698W | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs149761638, COSV99850734; called by muse, mutect2, varscan2
- ANKAR | c.454T>C p.Y152H | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99854684; called by muse, mutect2, varscan2
- AP1S2 | c.391C>G p.L131V | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV100236941; called by muse, varscan2
- APAF1 | c.2857A>G p.T953A (on ENST00000551964 / NM_181861.2; = p.T899A on NM_001160.3) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as rs763464521, CM068142, COSV100244443; called by muse, mutect2, varscan2
- ARHGAP21 | c.3443G>A p.R1148Q | Missense Mutation (SNP) | VAF 36/45 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100256342; called by muse, mutect2, varscan2
- ARID4B | c.128G>T p.R43I | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV99936368; called by muse, mutect2
- ATP2B3 | c.2977G>A p.E993K | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as COSV99685892; called by muse, mutect2, varscan2
- CADM3 | c.146A>C p.K49T (on ENST00000368125 / NM_001127173.3; = p.K83T on NM_021189.5) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.81); PolyPhen benign (0.017); catalogued as COSV100930418; called by muse, mutect2, varscan2
- CDC42BPA | c.1391A>C p.E464A | Missense Mutation (SNP) | VAF 41/54 reads (76%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as COSV100506940; called by muse, mutect2, varscan2
- CLEC12A | c.58A>C p.K20Q | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV100429700; called by muse, mutect2, varscan2
- CNBD1 | c.1187T>G p.L396R | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV73072298, COSV73072404, COSV73073941; called by muse, mutect2, varscan2
- CNTNAP5 | c.838C>T p.Q280* | Nonsense Mutation (SNP) | VAF 11/31 reads (35%) | catalogued as COSV101444244, COSV70485290; called by muse, mutect2, varscan2
- COL7A1 | c.6523C>A p.P2175T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV100097770; called by muse, mutect2, varscan2
- DNAH7 | c.3808C>T p.L1270F | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.538); catalogued as COSV100417651; called by muse, mutect2, varscan2
- DNAH8 | c.5780A>T p.K1927I | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV100547266; called by muse, mutect2, varscan2
- DNAH9 | c.3468A>C p.K1156N | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as COSV52378786; called by muse, mutect2, varscan2
- DSCAM | c.2356A>C p.I786L | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV101261570; called by muse, mutect2, varscan2
- EBF2 | c.1468T>G p.L490V | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.816); catalogued as rs1156879434, COSV68778596, COSV68780628; called by muse, mutect2, varscan2
- EDNRB | c.856A>C p.S286R (on ENST00000377211 / NM_001201397.1; = p.S196R on NM_000115.5) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57523970; called by muse, mutect2, varscan2
- EPB41L3 | c.3213A>C p.K1071N | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59448617, COSV59460416; called by muse, mutect2, varscan2
- FAT3 | c.1801T>G p.S601A | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99971251; called by muse, mutect2, varscan2
- FZD4 | c.305A>T p.Y102F | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.649); catalogued as COSV101536078; called by muse, mutect2, varscan2
- GALNT14 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 75/172 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757465089, COSV61104517; called by muse, mutect2, varscan2
- GRIN3A | c.1721A>C p.K574T | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as COSV100701851; called by muse, mutect2, varscan2
- GRK7 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs1461794918, COSV53823040; called by muse, mutect2, varscan2
- GTPBP10 | c.433C>G p.L145V | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99746245; called by muse, mutect2, varscan2
- H1-1 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV99772203; called by muse, mutect2
- HERC2 | c.6565G>A p.E2189K | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.034); catalogued as COSV55325904, COSV99872560; called by muse, mutect2, varscan2
- HIKESHI | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.038); catalogued as COSV99563663; called by muse, mutect2, varscan2
- HTR1B | c.380C>A p.S127* | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | catalogued as COSV100885493, COSV64052020; called by muse, mutect2, varscan2
- ITIH1 | c.1431A>C p.K477N | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99835631; called by muse, mutect2, varscan2
- ITPRIPL2 | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101198239; called by muse, mutect2, varscan2
- JAKMIP1 | c.2391A>C p.E797D | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV101290923, COSV68951388; called by muse, mutect2, varscan2
- KCNS2 | c.1355T>G p.V452G | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99751477; called by muse, mutect2, varscan2
- LAMA2 | c.7435T>G p.L2479V | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.821); catalogued as CD982731, COSV101370845; called by muse, mutect2, varscan2
- LHFPL6 | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101095680; called by muse, mutect2, varscan2
- LRP1B | c.1998A>C p.E666D | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV101255039, COSV67254142; called by muse, mutect2, varscan2
- MAGEA12 | c.744A>C p.Q248H | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.092); catalogued as COSV100756767, COSV63294236; called by muse, mutect2, varscan2
- MAGEC1 | c.3047A>G p.E1016G | Missense Mutation (SNP) | VAF 43/71 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV53569044; called by muse, mutect2, varscan2
- MAP3K13 | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99407997; called by muse, mutect2, varscan2
- MBD5 | c.346A>G p.M116V | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV101290273; called by muse, mutect2, varscan2
- MBD5 | c.1292C>T p.S431L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as COSV101290274; called by muse, mutect2, varscan2
- MEIS2 | c.43G>T p.D15Y (on ENST00000561208 / NM_170675.5; = p.D2Y on NM_002399.3) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV99577385; called by muse, mutect2
- MOCS1 | c.1112G>C p.S371T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV99227153; called by muse, varscan2
- MUC5B | c.7856C>A p.T2619N | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV101500795; called by muse, mutect2, varscan2
- NCAPG | c.646C>G p.R216G | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99266197; called by muse, mutect2, varscan2
- NDST4 | c.895T>C p.S299P | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.02); catalogued as COSV99997936; called by muse, mutect2, varscan2
- NIPBL | c.4621T>G p.F1541V | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99242745; called by muse, mutect2, varscan2
- NPAP1 | c.644A>G p.K215R | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs1040939821, COSV100276221, COSV61510789; called by muse, mutect2
- NRG3 | c.1880A>C p.N627T (on ENST00000404547 / NM_001370084.1; = p.N603T on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.995); catalogued as COSV64543908; called by muse, mutect2, varscan2
- NRXN1 | c.4247T>C p.L1416P | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100640746, COSV100640748; called by muse, mutect2, varscan2
- NT5DC3 | c.1208G>C p.G403A | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101231048; called by muse, mutect2
- NUP98 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV61432352; called by muse, mutect2
- OR10C1 | c.881G>A p.R294Q (on ENST00000622521; = p.R292Q on NM_013941.3) | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as rs766276149, COSV65822300; called by muse, mutect2, varscan2
- OR10J1 | c.529T>G p.F177V | Missense Mutation (SNP) | VAF 72/170 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV71128128; called by muse, mutect2, varscan2
- OR10J3 | c.892C>G p.Q298E | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as COSV100171894, COSV59954060; called by muse, mutect2, varscan2
- OR11H12 | c.355T>G p.F119V | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101612534; called by mutect2, varscan2
- OR2C1 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs765204895, COSV59239680; called by muse, mutect2, varscan2
- OR2T12 | c.584A>G p.N195S | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.021); catalogued as COSV100528005, COSV58775968; called by muse, mutect2, varscan2
- OR4C12 | c.395C>T p.T132I | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.015); catalogued as rs1555020244, COSV100078307, COSV100078689; called by muse, mutect2, varscan2
- OR4C16 | c.403A>C p.S135R | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as rs1404669415, COSV58940425, COSV58941301, COSV58942700; called by muse, mutect2, varscan2
- OR51B2 | c.238A>C p.M80L | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100173533; called by muse, mutect2, varscan2
- OR6X1 | c.340A>C p.T114P | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as COSV100020668; called by muse, mutect2, varscan2
- OR8K5 | c.922T>A p.*308Rext*? | Nonstop Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100537336; called by muse, mutect2, varscan2
- PGR | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); catalogued as COSV99677964; called by muse, mutect2
- PIP4K2C | c.997G>A p.G333R | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.085); catalogued as rs973052423, COSV100533807; called by muse, mutect2, varscan2
- PLEKHA3 | c.374A>G p.D125G | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV99317903; called by muse, mutect2
- PPL | c.456G>T p.Q152H | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.656); catalogued as COSV100631078; called by muse, mutect2, varscan2
- PRICKLE1 | c.1978G>A p.V660I | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as rs143947284; called by muse, mutect2, varscan2
- PRPF40A | c.486A>C p.L162F | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.644); catalogued as rs1229728567, COSV100583034; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1304T>C p.L435P (on ENST00000352766; = p.L356P on NM_181334.5) | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV100424693; called by muse, mutect2, varscan2
- PTGER3 | c.1191A>T p.E397D | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.003); catalogued as COSV100657422, COSV63035603, COSV63040906; called by muse, mutect2, varscan2
- PUS3 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs772532957; called by muse, mutect2
- QARS1 | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1370265763, COSV100070282; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RBM25 | c.1292G>A p.R431Q | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as rs757997180, COSV56202846, COSV99999072; called by muse, mutect2, varscan2
- REV3L | c.6161A>G p.D2054G | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as rs750229185, COSV100725695; called by muse, mutect2, varscan2
- RNASE2 | c.20C>G p.T7S | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.935); catalogued as COSV100482111; called by muse, mutect2, varscan2
- RTKN2 | c.1616C>T p.S539L | Missense Mutation (SNP) | VAF 64/78 reads (82%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs191159688, COSV59523672; called by muse, mutect2, varscan2
- SACS | c.3769G>A p.G1257R | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.161); catalogued as rs767797830, CM138554, COSV101207742; called by muse, mutect2, varscan2
- SERPINA7 | c.214A>G p.S72G | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV100568492; called by muse, mutect2, varscan2
- SLC12A5 | c.1759T>G p.F587V (on ENST00000454036 / NM_001134771.2; = p.F564V on NM_020708.5) | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV99716883; called by muse, varscan2
- SLC25A45 | c.15A>C p.E5D | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.329); catalogued as COSV99587427; called by muse, mutect2, varscan2
- SLC38A10 | c.2503G>C p.D835H | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV99917939; called by muse, mutect2
- SPEF2 | c.5372A>C p.K1791T | Missense Mutation (SNP) | VAF 63/114 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs546674187, COSV100289482, COSV57426909, COSV57427611; called by muse, mutect2, varscan2
- SYPL1 | c.77T>C p.L26P | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV99163470; called by muse, mutect2, varscan2
- TBC1D9 | c.338C>G p.T113R | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as COSV101464411; called by muse, mutect2, varscan2
- TBPL1 | c.90G>C p.K30N | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as COSV52784120, COSV99393974; called by muse, mutect2, varscan2
- TC2N | c.1271T>G p.I424S | Missense Mutation (SNP) | VAF 70/170 reads (41%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.575); catalogued as COSV100563123; called by muse, mutect2, varscan2
- TCTE3 | c.493A>C p.S165R | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100825449; called by muse, mutect2, varscan2
- THBD | c.941A>G p.Y314C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV101001924; called by muse, mutect2, varscan2
- THSD4 | c.792A>C p.E264D | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV99967179; called by muse, mutect2, varscan2
- THSD7A | c.3477A>C p.K1159N | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.21); catalogued as COSV101439800; called by muse, mutect2, varscan2
- TRIM21 | c.346C>T p.Q116* | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as COSV99587688, COSV99587924; called by muse, mutect2, varscan2
- TRIM51 | c.1190T>A p.L397H | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99793175; called by muse, mutect2, varscan2
- TRPC6 | c.1421A>G p.E474G | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.079); catalogued as COSV100723767; called by mutect2, varscan2
- TSHZ3 | c.803A>C p.K268T | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99552824; called by muse, mutect2, varscan2
- TTC29 | c.518T>C p.I173T | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV100284635; called by muse, mutect2, varscan2
- TTN | c.32010A>C p.E10670D (on ENST00000591111; = p.E9743D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/31 reads (48%) | PolyPhen probably damaging (0.98); catalogued as COSV100630707; called by muse, mutect2, varscan2
- UNC45B | c.2795A>C p.*932Sext*45 | Nonstop Mutation (SNP) | VAF 8/22 reads (36%) | catalogued as rs1345627183, COSV99269271; called by muse, mutect2, varscan2
- VARS2 | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753490759, COSV99462273; called by muse, mutect2, varscan2
- VTCN1 | c.552A>C p.Q184H | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.738); catalogued as COSV60223389; called by muse, mutect2, varscan2
- WASF3 | c.947C>A p.S316Y | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.087); catalogued as COSV100099574; called by muse, mutect2, varscan2
- ZC3H6 | c.2464G>A p.D822N | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.632); catalogued as rs557004552, COSV100674834, COSV59670181; called by muse, mutect2, varscan2
- ZGRF1 | c.1235G>A p.S412N | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100005798; called by muse, mutect2
- ZMYND15 | c.931C>T p.R311* | Nonsense Mutation (SNP) | VAF 28/77 reads (36%) | catalogued as rs148161063; called by muse, varscan2
- ZNF208 | c.948A>C p.K316N | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.581); catalogued as COSV101237199, COSV68099423, COSV68111580; called by muse, mutect2, varscan2
- ZNF257 | c.1493G>T p.R498L | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV101448171, COSV71310220; called by muse, mutect2, varscan2
- ZNF416 | c.1436C>T p.S479F | Missense Mutation (SNP) | VAF 11/164 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.694); catalogued as COSV99543966; called by muse, mutect2
- ZNF570 | c.256+1G>C p.X86_splice | Splice Site (SNP) | VAF 4/33 reads (12%) | catalogued as COSV100356304; called by muse, mutect2, varscan2
- ZNF587 | c.1472C>T p.P491L | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as rs1382609523, COSV57146572; called by muse, mutect2
- ZNF670 | c.1089A>C p.K363N | Missense Mutation (SNP) | VAF 90/132 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV63607660; called by muse, mutect2, varscan2
- ZNF677 | c.1165A>C p.S389R | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.717); catalogued as COSV100448184; called by muse, varscan2
- ZNF696 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.304); catalogued as COSV100350656; called by muse, mutect2, varscan2
- ZNF791 | c.952C>T p.H318Y | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58480253; called by muse, mutect2, varscan2
- ZNF800 | c.541G>T p.V181L | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV99758215; called by muse, mutect2, varscan2
- ZNF804A | c.421A>C p.T141P | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100170273; called by muse, mutect2, varscan2
- ADAMTS18 | c.973-1_974dup p.V325dup | In Frame Ins (INS) | VAF 9/34 reads (26%) | called by mutect2, pindel, varscan2
- BBOX1 | c.986_987insAAGTTAC p.F330Sfs*9 | Frame Shift Ins (INS) | VAF 18/39 reads (46%) | called by mutect2, pindel, varscan2
- DYNC2H1 | c.8438A>T p.N2813I | Missense Mutation (SNP) | VAF 2/8 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2
- NFE2L2 | c.1334_1339del p.K445_S447delinsT | In Frame Del (DEL) | VAF 56/141 reads (40%) | called by mutect2, pindel, varscan2
- OR11H1 | c.576T>G p.D192E | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.007); called by mutect2, varscan2
- PCDHB14 | c.1781G>T p.G594V | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.314); called by muse, mutect2
- PRAMEF15 | c.473A>C p.K158T | Missense Mutation (SNP) | VAF 89/968 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.747); called by muse, mutect2
- AP1G2 | c.1587A>C p.T529= | Silent (SNP) | VAF 27/59 reads (46%) | catalogued as COSV99846350; called by muse, mutect2, varscan2
- CNKSR2 | c.909A>G p.S303= | Silent (SNP) | VAF 27/52 reads (52%) | catalogued as COSV99668755, COSV99669825; called by muse, mutect2, varscan2
- COL4A1 | c.4917C>T p.S1639= | Silent (SNP) | VAF 51/102 reads (50%) | catalogued as rs1355587586, COSV101011614; called by muse, mutect2, varscan2
- CRCT1 | c.273G>T p.R91= | Silent (SNP) | VAF 12/17 reads (71%) | catalogued as COSV100524327; called by muse, mutect2, varscan2
- CSMD3 | c.6066T>C p.S2022= (on ENST00000297405 / NM_001363185.1; = p.S1918= on NM_052900.3) | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV99848228; called by muse, mutect2, varscan2
- CST4 | c.309C>A p.T103= | Silent (SNP) | VAF 17/158 reads (11%) | catalogued as COSV99463434; called by muse, mutect2, varscan2
- DDX25 | c.1107C>T p.S369= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs759664197, COSV54990116; called by muse, mutect2
- DHRS13 | c.387C>T p.G129= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as COSV100242141; called by muse, mutect2, varscan2
- DNAH8 | c.10128T>C p.A3376= | Silent (SNP) | VAF 5/58 reads (9%) | catalogued as COSV100547267; called by muse, mutect2
- DSCAM | c.6015C>T p.Y2005= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs370553162; called by muse, mutect2, varscan2
- FAM135B | c.1425A>G p.E475= | Silent (SNP) | VAF 18/87 reads (21%) | catalogued as COSV99417889, COSV99427864; called by muse, mutect2, varscan2
- KCNK9 | c.717C>T p.L239= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV100271740; called by muse, mutect2, varscan2
- KIAA1755 | c.1941G>A p.L647= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV99642733; called by muse, mutect2, varscan2
- KLHL11 | c.1342C>T p.L448= | Silent (SNP) | VAF 28/109 reads (26%) | catalogued as COSV100044480, COSV59862196; called by muse, mutect2, varscan2
- LCE1E | c.123T>C p.S41= | Silent (SNP) | VAF 27/141 reads (19%) | catalogued as COSV100908575; called by muse, mutect2, varscan2
- LRP12 | c.156G>A p.E52= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as rs1211295227, COSV99408392; called by muse, mutect2, varscan2
- MAP10 | c.78A>T p.I26= | Silent (SNP) | VAF 20/182 reads (11%) | catalogued as COSV101406566; called by muse, mutect2, varscan2
- MC2R | c.540G>A p.S180= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as rs779604431, COSV59618287; called by muse, mutect2, varscan2
- MUC15 | c.528T>G p.T176= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV55553612; called by muse, mutect2, varscan2
- NT5DC3 | c.1209C>G p.G403= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV101231047; called by muse, mutect2
- OLIG3 | c.519C>T p.H173= | Silent (SNP) | VAF 18/30 reads (60%) | catalogued as rs138056559; called by muse, mutect2, varscan2
- OR10X1 | c.666T>C p.G222= | Silent (SNP) | VAF 49/70 reads (70%) | catalogued as COSV100936714; called by muse, mutect2, varscan2
- OR4X2 | c.585A>G p.G195= | Silent (SNP) | VAF 35/106 reads (33%) | catalogued as rs1435864959, COSV100183349; called by muse, mutect2, varscan2
- PAQR8 | c.667C>T p.L223= | Silent (SNP) | VAF 30/75 reads (40%) | catalogued as COSV100658537; called by muse, mutect2, varscan2
- PATJ | c.1245T>C p.N415= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV100335004; called by muse, mutect2, varscan2
- PPP1R3A | c.1869A>T p.G623= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as COSV99494359; called by muse, mutect2, varscan2
- PRAMEF5 | c.303A>G p.Q101= | Silent (SNP) | VAF 12/185 reads (6%) | called by muse, mutect2
- PRG4 | c.1287C>T p.P429= | Silent (SNP) | VAF 56/108 reads (52%) | catalogued as COSV100798331; called by muse, varscan2
- RAD51C | c.699C>T p.H233= | Silent (SNP) | VAF 40/54 reads (74%) | catalogued as COSV100507120; called by muse, mutect2, varscan2
- RPH3A | c.630G>A p.R210= (on ENST00000389385 / NM_001143854.2; = p.R206= on NM_014954.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/79 reads (48%) | catalogued as rs1446286056, COSV101231897; called by muse, mutect2, varscan2
- SIGLEC12 | c.966T>C p.T322= (on ENST00000291707 / NM_053003.4; = p.T204= on NM_033329.2) | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV52461461; called by muse, mutect2, varscan2
- SIGLEC14 | c.1128C>T p.L376= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV99707936; called by muse, mutect2, varscan2
- TTI2 | c.162C>T p.D54= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as COSV100659823; called by muse, mutect2, varscan2
- UBQLNL | c.228T>A p.G76= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as rs747040695, COSV100975586; called by muse, mutect2, varscan2
- ZFHX4 | c.9058T>C p.L3020= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV99267930, COSV99268688; called by muse, mutect2, varscan2
- ZFP28 | c.1284T>C p.T428= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as COSV100019895, COSV56738164; called by muse, varscan2
- ZNF540 | c.894T>C p.S298= | Silent (SNP) | VAF 5/59 reads (8%) | catalogued as COSV57110461; called by muse, mutect2
- ZNF668 | c.1587G>A p.T529= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as COSV56218655; called by muse, mutect2, varscan2
- ZPBP | c.213A>G p.K71= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV99250576; called by muse, mutect2, varscan2
- COL11A1 | c.898-272A>C | Intron (SNP) | VAF 33/83 reads (40%) | catalogued as rs148225616, COSV62181335; called by muse, mutect2, varscan2
- DCAF13 | chr8:103415274 G>A | 5'Flank (SNP) | VAF 25/106 reads (24%) | catalogued as COSV99884690; called by muse, mutect2, varscan2
- HERC2P3 | n.756C>T | RNA (SNP) | VAF 20/160 reads (13%) | called by muse, mutect2, varscan2
- IGLL5 | chr22:22900981 C>T | 3'Flank (SNP) | VAF 12/174 reads (7%) | called by muse, mutect2
- SNORD116-29 | n.18A>C | RNA (SNP) | VAF 16/61 reads (26%) | catalogued as rs543695444; called by muse, mutect2, varscan2
- ZBTB37 | chr1:173864427 A>C | 5'Flank (SNP) | VAF 15/42 reads (36%) | catalogued as rs374983711; called by muse, mutect2, varscan2
